Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A3WE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A3WE-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]

Med Rec No: [REDACTED]

DOB: [REDACTED] (Age: [REDACTED])

Gender: F

Physician(s): [REDACTED]

cc:

Client: [REDACTED]

Location: [REDACTED]

Pt. Phone no [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

History/Clinical Dx: Anemia, pelvic mass

Postoperative Dx: Pending pathology examination

Normal/Normal

ICD-0-3 coding N/A

Site: Endometrium C54.1

W 5/2/12

Specimen(s) Received:

Uterus and cervix

DIAGNOSIS:

Uterus and cervix:

1. Cervix with no pathologic abnormality
2. Disordered proliferative endometrium and endometrial polyp
3. Adenomyosis
3. Leiomyomata

Gross Description

Received: In formalin is a single segment of previously opened, unoriented, soft tan tissue

Labeled: "1 cervix, uterus"

Weight: 330.0 gm

Size: 12.0 x 8.9 x 8.0 cm

Appearance:

Serosal surface: Smooth, shiny, tan with prominent subserosal bulging; asymmetric

Cervix: Smooth, shiny, with no lesions

Endometrium: 0.2 cm, smooth, tan with areas of hemorrhage and mucoid material. There is a polyp, 0.4 x 0.3 x 0.3 cm. There is a possible tan, granular area, 0.6 x 0.4 x 0.1 cm.

Myometrium: 4.3 cm, diffuse areas of adenomyosis, largest up to 4.0 x 3.5 x 2.0 cm

Myomas

Number: Multiple

Size: Largest up to 6.2 x 5.0 x 5.0 cm

Appearance: White with whorled cut surfaces, well-circumscribed, with no areas of hemorrhage, calcifications or necrosis.

Other: None

KEY TO CASSETTES:

- 1 - Cervix
- 2 - Lower uterine segment
- 3 - Polyp
- 4 - Endometrium, possible granular area described above

Preanalytical Submissions

Preanalytical Submissions

Preanalytical Submissions

Preanalytical Submissions

[page 2 of 2]
[REDACTED]

[REDACTED]

Surgical Pathology Report

[REDACTED]

5-6 - Endomyometrium
7 - Representative of areas of adenomyosis
8-10 - Representative of myomas

[REDACTED]

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file 120bd16d-bf2e-443d-a232-1927a8dee1e1 (TCGA-FL-A3WE.803BA1B3-9F78-43B8-B9CA-81D309E9FEDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).